CMI case ASCProject_0134 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/48e5aa55-715f-4b70-89d9-b3113b6cafba

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Skin of scalp and neck; Site of resection or biopsy: Skin of scalp and neck; Age at diagnosis: 62.8 years (22,935 days).

Biospecimens (3 samples)
- Sample ASCProject_0134_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Sample ASCProject_0134_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Scalp; Preservation method: FFPE.
- Sample ASCProject_0134_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Forehead; Preservation method: FFPE.
